Somatic mutation profile of tumor specimen C3L-06368-57 (aliquot CPT0410410002) from CPTAC case C3L-06368, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 50.0 years (18,259 days).
Specimen C3L-06368-57: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba18c8dd-cac2-465a-ba60-11c155ba4f02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06368-51 (Buccal Cell Normal), aliquot CPT0410360001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81779d1d-ecba-4dc8-9c38-8fbdc2267390

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.863_864insCTTG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 21/67 reads (31%) | catalogued as COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- TET2 | c.374del p.F125Sfs*3 | Frame Shift Del (DEL) | VAF 113/258 reads (44%) | called by mutect2, pindel, varscan2
- CELSR2 | c.8649G>A p.P2883= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as rs753470320; called by muse, mutect2, varscan2
